Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A4NE, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A4NE-01A (Primary Tumor).

DIAGNOSIS:

B. Liver, right lobe and portion of segment 4B, resection: Grade 3 (of 4) hepatocellular carcinoma is identified forming a dominant mass, 14.5 x 8.7 x 6.8 cm, with innumerable satellite nodules (ranging in size from 0.1 cm to 4.4 cm in greatest dimension). The tumors are confined to the liver. The liver parenchyma resection margins are negative for tumor (minimum tumor free margin, 0.3 cm). Macroscopic large vessel (venous) invasion is absent. Microscopic (small vessel) invasion is absent. Multiple (3) perihepatic lymph nodes are negative for tumor.

A. Gallbladder, cholecystectomy: Chronic cholecystitis.

With available surgical material [AJCC pT3aN0] (7th edition,

This final pathology report is based on the gross/macroscopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

QW 12/24/12

Case ID (circle):		☒

2/20/12

Source: NCI Genomic Data Commons file 945a91f4-b78d-45c6-a4d2-366071c660de (TCGA-DD-A4NE.8E3E5E19-6A21-44B1-B000-F90EA27F6EE0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).